HCMI case HCM-CSHL-0608-C17 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc1f75d5-8910-45ee-ae52-0d34ee41ee02

Demographics
Sex at birth: female; Year of birth: 1979; Vital status: Alive.

Diagnoses (2)
1. Atypical carcinoid tumor (the primary disease): ICD-O-3 morphology code: 8249/3; ICD-10 code: C17; Tissue or organ of origin: Small intestine, NOS; Classification of tumor: primary; Age at diagnosis: 39.8 years (14,534 days); AJCC staging edition: 8th; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Lymph node, NOS.
   Pathology details: Lymph nodes positive: 9; Lymph nodes tested: 29.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Lanreotide Acetate; Treatment intent type: Neoadjuvant; Days to treatment start: -490 days (-1.3 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Everolimus + Fluorouracil + Streptozocin; Treatment intent type: Neoadjuvant; Days to treatment start: -459 days (-1.3 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -9 days.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, for residual disease; neoadjuvant Radiation Therapy, NOS.
2. Atypical carcinoid tumor: ICD-O-3 morphology code: 8249/6; ICD-10 code: C77.2; Tissue or organ of origin: Small intestine, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 39.8 years (14,534 days).

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 187 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 53.

Molecular and laboratory tests
- CD56 (IHC): Negative.
- CHGA (IHC): Positive.
- Ki67 (IHC): 22; Cell count: 700.
- Ki67 (IHC): 3 percent.
- SYP (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 172 cm; BMI: 25.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0608-C17-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0608-C17-06A-01-S1-HE: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 92; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 55; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0608-C17-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 53; Percent tumor nuclei: 92; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 47; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0608-C17-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0608-C17-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
